Gene-level copy-number profile of tumor specimen TCGA-85-8580-01A from TCGA case TCGA-85-8580, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.8 years (19,301 days).
Specimen TCGA-85-8580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0223a6f5-8362-4755-bbcc-48a5e8473fe8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8580-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/929c3988-96c8-4d1c-93b2-98cc1bc6d27e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 217; copy number 1: 20,090; copy number 2: 33,031; copy number 3: 4,634; copy number 4: 1,774; copy number 5: 60; copy number 6: 1; copy number 7: 8; copy number 8: 2; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8580-01A-31D-2391-01): tumor purity 0.33, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 217 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:8,775,402–9,602,728, 16 genes (within-gene range 0–2): RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2.
- chr4:177,728,757–190,092,279, 195 genes (within-gene range 0–1) (broad region; genes not listed).
- chr10:36,432,882–36,626,138, 6 genes: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 72 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 6: AC010983.1.
- chr3:114,314,500–115,147,288, 1 gene, copy number 5 (within-gene range 4–5): ZBTB20.
- chr3:114,684,580–117,997,592, 29 genes, copy number 5 (within-gene range 4–15): ZBTB20-AS2, MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1, LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:176,763,233–179,267,002, 35 genes, copy number 5–11: RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1.
- chr4:44,944,015–44,944,961, 1 gene, copy number 5: PRDX4P1.
- chr5:53,297,872–53,326,565, 1 gene, copy number 7 (within-gene range 2–7): AC027329.1.
- chr5:125,886,285–125,968,085, 2 genes, copy number 5: AC010587.1, RPSAP37.
- chr7:137,164,043–137,164,612, 1 gene, copy number 5: AC009517.1.
- chr8:56,776,283–56,776,874, 1 gene, copy number 8: AC009597.2.

Autosomal genes at a single copy (total copy number 1): 17,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
